Somatic mutation profile of tumor specimen TCGA-P5-A735-01A (aliquot TCGA-P5-A735-01A-11D-A32B-08) from TCGA case TCGA-P5-A735, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 38.7 years (14,152 days).
Specimen TCGA-P5-A735-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d2b9b21-fceb-4fda-b461-2fb78109d90d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P5-A735-10A (Blood Derived Normal), aliquot TCGA-P5-A735-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/15eb6a88-3712-4cbb-863d-5fefff79a67a

The open-access MAF lists 25 somatic variants for this specimen: 22 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 17, Silent 3, Frame Shift Del 3, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 28/58 reads (48%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- MKRN3 | c.482del p.P161Rfs*10 | Frame Shift Del (DEL) | VAF 10/23 reads (43%) | catalogued as rs763195944; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.842A>T p.D281V | Missense Mutation (SNP) | VAF 11/37 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs587781525, CM004343, CM056068, CM114008, COSV52694391, COSV52729448, COSV52815868; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.96+1G>A p.X32_splice | Splice Site (SNP) | VAF 27/55 reads (49%) | hotspot (GDC flag); catalogued as CS167193, COSV52662718, COSV52757202, COSV53162510; called by muse, mutect2, varscan2
- ADAMTS19 | c.949A>G p.S317G | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1561551565, COSV99178938; called by muse, mutect2, varscan2
- AGBL2 | c.188A>G p.K63R | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100101723; called by muse, mutect2
- CCDC110 | c.1888C>T p.L630F | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.181); catalogued as rs775158306, COSV100293954; called by muse, mutect2, varscan2
- CEBPZ | c.2101A>G p.R701G | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746885067, COSV99305234; called by muse, mutect2, varscan2
- CNTN4 | c.2518T>A p.Y840N | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100639298; called by muse, mutect2, varscan2
- ELF4 | c.616G>A p.G206S | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100257385; called by muse, mutect2, varscan2
- FAT1 | c.9601G>A p.A3201T | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs750903093, COSV101499381; called by muse, varscan2
- L1CAM | c.1625C>T p.S542F | Missense Mutation (SNP) | VAF 76/193 reads (39%) | SIFT tolerated (0.6); PolyPhen benign (0.221); catalogued as COSV100649184; called by muse, mutect2, varscan2
- LBP | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 60/133 reads (45%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.506); catalogued as COSV99460901; called by muse, mutect2, varscan2
- MALT1 | c.421G>A p.G141R | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100618722; called by muse, mutect2
- PLEKHA4 | c.1743G>C p.K581N | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV99612610; called by muse, mutect2, varscan2
- PLEKHO2 | c.1259C>T p.S420L | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.206); catalogued as rs543499350, COSV100060754; called by muse, mutect2
- SPTA1 | c.1409G>A p.R470H | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs370498187; called by muse, mutect2, varscan2
- TACC2 | c.1828G>C p.V610L | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV100552434; called by muse, mutect2, varscan2
- TMEM19 | c.962T>C p.I321T | Missense Mutation (SNP) | VAF 106/228 reads (46%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs746676238, COSV99876973; called by muse, mutect2, varscan2
- ATRX | c.600dup p.F201Lfs*2 | Frame Shift Ins (INS) | VAF 51/141 reads (36%) | called by mutect2, pindel, varscan2
- FCGBP | c.9101del p.L3034Rfs*163 | Frame Shift Del (DEL) | VAF 34/157 reads (22%) | called by mutect2, pindel, varscan2
- KIFC1 | c.1081_1082del p.S361Wfs*10 | Frame Shift Del (DEL) | VAF 46/114 reads (40%) | called by mutect2, pindel, varscan2
- ARID1A | c.4656G>A p.Q1552= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as COSV100251851, COSV61388410; called by muse, mutect2, varscan2
- SLC11A1 | c.468G>A p.T156= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs767438872, COSV99262159; called by muse, mutect2, varscan2
- SLC17A2 | c.489A>T p.T163= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV99614423; called by muse, mutect2, varscan2
